Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A5R2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A5R2-01A (Primary Tumor).

[page 1 of 2]
MEDICAL CENTER
LABORATORY

PAGE: 1

Specimen Inquiry

PATIENT:

ACCT #:

LOC:

U#:

REG DR:

SPEC #:

CLINICAL HISTORY:

(ICD 627.1)

SPECIMEN/PROCEDURE:

1. CERVICAL BIOPSY

IMPRESSION:

CERVIX, BIOPSY:

Invasive squamous cell carcinoma, large cell nonkeratinizing type, poorly differentiated.

COMMENT:

The case is reviewed in

GROSS DESCRIPTION:

Received in formalin labeled _____ and with the patient's name, the specimen consists of multiple fragments of pale tan tissue intermixed with a moderate amount of clotted blood measuring 0.7 x 0.5 x 0.2 cm in aggregate. The specimen is entirely submitted in one cassette.

COPIES TO:

No Primary or Family Physician

path ICD-O-3
Carcinoma, large cell-squamous
cell, non-keratinizing NOS 8672/3
CHF Carcinoma, squamous cell NOS
8670/3
Site: Cervix NOS C53.9
JW 4/12/13

CPT Codes:

CERVICAL BIOPSY/88305

[page 2 of 2]
SPEC #:

(Continued) Page: 2

ICD9 Codes:

180.9

I have personally reviewed the material
(specimen/slide) and approve this final report.

** END OF REPORT **

HPV Discrepancy		✓

Source: NCI Genomic Data Commons file 29881073-2ed3-43cd-997f-2f5bafde2edc (TCGA-Q1-A5R2.D5BD3FE8-6CE0-41A1-A9CB-FE8874C4A16F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).